FM case AD9394 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/b046f0ef-8a47-4a64-a70d-8829fc5276dd

Male, 57.7 years: Melanoma, NOS (ICD-O-3 8720/3) of the head, face or neck; specimen biopsied or resected from the nasal cavity. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
